Somatic mutation profile of tumor specimen MMRF_2490_1_BM_CD138pos (aliquot MMRF_2490_1_BM_CD138pos_T1_KHS5U_K15206) from MMRF case MMRF_2490, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 81.4 years (29,723 days).
Specimen MMRF_2490_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e269b3b7-91a8-4a1a-9485-aba043b559dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2490_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2490_1_PB_WBC_C3_KHS5U_K15207; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f383b8f5-9937-4fbb-ab47-17f97bb41dc5

The open-access MAF lists 471 somatic variants for this specimen: 175 protein-altering or splice-affecting, 45 silent, 251 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 151, 3'UTR 130, Intron 50, Silent 45, 5'UTR 29, 3'Flank 17, 5'Flank 13, RNA 12, Splice Site 7, Splice Region 5, Nonsense Mutation 5, Frame Shift Ins 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIM1 | c.72G>C p.K24N | Missense Mutation (SNP) | VAF 70/135 reads (52%) | hotspot (GDC flag); SIFT tolerated (0.48); PolyPhen benign (0.062); catalogued as COSV65164988, COSV65166078, COSV65166386; called by muse, varscan2
- ABI2 | c.1076G>A p.R359H (on ENST00000295851 / NM_001375719.1; = p.R292H on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 111/197 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.977); catalogued as COSV53693509; called by muse, mutect2, varscan2
- ADAM18 | c.630A>C p.K210N | Missense Mutation (SNP) | VAF 58/118 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1307957555; called by muse, mutect2, varscan2
- ADAMTS16 | c.1831C>T p.R611C | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs746897394; called by muse, mutect2, varscan2
- ADAMTS5 | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs562532375, COSV53179217, COSV53180757; called by muse, mutect2, varscan2
- ADGRD1 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 58/107 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as rs749318936, COSV55446278; called by muse, mutect2, varscan2
- ALPG | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs568507509, COSV54964676; called by muse, mutect2, varscan2
- ARHGAP22 | c.1997C>T p.A666V | Missense Mutation (SNP) | VAF 103/226 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1479805702; called by muse, mutect2, varscan2
- ATRX | c.299A>G p.D100G | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as rs782377443; called by muse, mutect2, varscan2
- BHLHE22 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.013); catalogued as rs777622556; called by muse, mutect2, varscan2
- CATSPERB | c.2816A>G p.E939G | Missense Mutation (SNP) | VAF 78/175 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs773625043, COSV56438626; called by muse, mutect2, varscan2
- CDH18 | c.1565G>A p.R522K | Missense Mutation (SNP) | VAF 88/217 reads (41%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.542); catalogued as rs924924323; called by muse, mutect2, varscan2
- CDK11A | c.2010C>A p.N670K (on ENST00000378633 / NM_001313896.2; = p.N667K on NM_024011.4) | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1353376633; called by muse, mutect2
- CHD1 | c.4787+2T>C p.X1596_splice | Splice Site (SNP) | VAF 51/52 reads (98%) | catalogued as COSV52343165; called by muse, mutect2, varscan2
- CNTN6 | c.1253dup p.S419Vfs*33 | Frame Shift Ins (INS) | VAF 82/180 reads (46%) | catalogued as rs758676375; called by mutect2, varscan2
- COL1A1 | c.3197G>A p.R1066H | Missense Mutation (SNP) | VAF 54/100 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs752075205, COSV99867080; called by muse, mutect2, varscan2
- COMMD2 | c.83G>A p.G28E | Missense Mutation (SNP) | VAF 105/224 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.9); catalogued as COSV71946366; called by muse, mutect2, varscan2
- COPZ2 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 91/225 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1206056623; called by muse, mutect2, varscan2
- CSMD3 | c.7749G>T p.Q2583H (on ENST00000297405 / NM_001363185.1; = p.Q2479H on NM_052900.3) | Missense Mutation (SNP) | VAF 77/239 reads (32%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as COSV52210194; called by muse, mutect2, varscan2
- DLGAP1 | c.2276C>T p.T759M | Missense Mutation (SNP) | VAF 66/109 reads (61%) | SIFT tolerated (0.16); PolyPhen benign (0.046); catalogued as rs1027822448, COSV59784080; called by muse, mutect2, varscan2
- DMD | c.6787C>T p.R2263C | Missense Mutation (SNP) | VAF 95/195 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs200045725; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DRC7 | c.1906C>T p.R636W | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as rs748847770, COSV100395767, COSV61054971; called by muse, mutect2, varscan2
- DSG1 | c.679A>G p.R227G | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148679825; called by muse, mutect2, varscan2
- DTX1 | c.162G>C p.E54D | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.131); catalogued as COSV57501098; called by muse, mutect2, varscan2
- EGR1 | c.85A>G p.M29V | Missense Mutation (SNP) | VAF 104/260 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); catalogued as rs768374163; called by muse, varscan2
- EIF2AK3 | c.1913G>A p.R638Q | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1288833379, COSV57546183; called by muse, mutect2, varscan2
- ENTPD6 | c.386C>T p.T129M | Missense Mutation (SNP) | VAF 141/276 reads (51%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.964); catalogued as rs545735578, COSV61751578; called by muse, mutect2, varscan2
- EPHA5 | c.1118T>G p.V373G | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56631937, COSV56681367; called by muse, mutect2, varscan2
- EVX1 | c.157G>A p.V53I | Missense Mutation (SNP) | VAF 48/86 reads (56%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99763829; called by muse, mutect2, varscan2
- FAM155B | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 103/192 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1405723573, COSV52935413; called by muse, mutect2, varscan2
- FAM8A1 | c.109C>G p.P37A | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.001); catalogued as rs971827574; called by muse, mutect2, varscan2
- FBXO41 | c.1115G>A p.R372Q | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.53); PolyPhen benign (0.273); catalogued as rs755439932; called by muse, varscan2
- GC | c.1263-1G>T p.X421_splice | Splice Site (SNP) | VAF 51/95 reads (54%) | catalogued as rs113175628; called by muse, mutect2, varscan2
- HDAC4 | c.107C>T p.T36M | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as rs760140223, COSV61860013; called by muse, mutect2, varscan2
- HDLBP | c.1096G>A p.V366I | Missense Mutation (SNP) | VAF 59/128 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0.023); catalogued as rs201275944; called by muse, mutect2, varscan2
- IFT74 | c.1127A>C p.E376A | Missense Mutation (SNP) | VAF 168/270 reads (62%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as COSV66286341; called by muse, mutect2, varscan2
- IGHV2-70D | c.344A>G p.Y115C | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1446744170; called by muse, varscan2
- IGHV3-30 | c.70G>A p.V24M | Missense Mutation (SNP) | VAF 79/177 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.963); catalogued as rs752144607; called by muse, mutect2, varscan2
- IGKV1D-8 | c.202C>T p.L68F | Missense Mutation (SNP) | VAF 75/162 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.168); catalogued as rs780966103; called by muse, mutect2, varscan2
- IGKV2-24 | c.170A>C p.Y57S | Missense Mutation (SNP) | VAF 104/247 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); catalogued as rs762363282; called by muse, mutect2, varscan2
- IGLV3-1 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 100/162 reads (62%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs368499668; called by muse, varscan2
- IGLV4-3 | c.196A>T p.I66L | Missense Mutation (SNP) | VAF 88/164 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs529123510; called by muse, varscan2
- IGLV4-3 | c.198A>G p.I66M | Missense Mutation (SNP) | VAF 74/162 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs1369537513; called by muse, varscan2
- INO80 | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 51/97 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62738681; called by muse, mutect2, varscan2
- JAKMIP1 | c.1358C>T p.T453M | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs775667524; called by muse, mutect2, varscan2
- KCNJ3 | c.352G>A p.G118S | Missense Mutation (SNP) | VAF 91/182 reads (50%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV54532081; called by muse, mutect2, varscan2
- LAMA1 | c.3412G>A p.A1138T | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs146317153; called by muse, mutect2
- LGALS1 | c.373G>A p.G125S | Missense Mutation (SNP) | VAF 121/258 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs767880851, COSV53222293; called by muse, mutect2, varscan2
- MAST4 | c.7190A>G p.E2397G (on ENST00000403625 / NM_001164664.2; = p.E2208G on NM_015183.3) | Missense Mutation (SNP) | VAF 74/161 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.687); catalogued as rs774634795; called by muse, mutect2, varscan2
- MRM2 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 64/146 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs376300149; called by muse, mutect2, varscan2
- MTOR | c.1657C>T p.R553C | Missense Mutation (SNP) | VAF 56/121 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.586); catalogued as rs1350423605, COSV63869396; called by muse, mutect2, varscan2
- NLRP5 | c.1417G>A p.V473M | Missense Mutation (SNP) | VAF 108/219 reads (49%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.557); catalogued as rs199475776; ClinVar: not provided; called by muse, mutect2, varscan2
- OLIG1 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV100287208; called by muse, varscan2
- PCDH7 | c.1043G>T p.G348V | Missense Mutation (SNP) | VAF 143/285 reads (50%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as COSV62343658; called by muse, mutect2, varscan2
- PCDHB16 | c.1120G>A p.D374N | Missense Mutation (SNP) | VAF 118/252 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53360584, COSV53366059; called by muse, mutect2, varscan2
- PHF24 | c.241C>T p.R81W | Missense Mutation (SNP) | VAF 88/245 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765926916; called by muse, mutect2, varscan2
- PIM1 | c.68C>T p.T23I | Missense Mutation (SNP) | VAF 66/144 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs546301253, COSV65165568, COSV65166041; called by muse, varscan2
- RAB8A | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 57/115 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1470442545; called by muse, mutect2, varscan2
- RBBP6 | c.2477G>A p.R826H | Missense Mutation (SNP) | VAF 105/198 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.719); catalogued as rs367639774; called by muse, mutect2, varscan2
- RPS6KA2 | c.1193A>C p.H398P | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV55832104; called by muse, mutect2, varscan2
- RRAS2 | c.67G>T p.G23C | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56329700, COSV56329705; called by muse, mutect2, varscan2
- RTN1 | c.1916G>A p.R639H | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749408245; called by muse, mutect2, varscan2
- SHANK2 | c.3266G>A p.R1089H | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781863842, COSV53606387; called by muse, mutect2, varscan2
- SULT1B1 | c.733C>A p.P245T | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); catalogued as COSV60209181; called by muse, mutect2, varscan2
- SYTL1 | c.748-8G>A | Splice Region (SNP) | VAF 40/67 reads (60%) | catalogued as rs1393653476; called by muse, mutect2, varscan2
- TANC2 | c.4534G>T p.G1512* | Nonsense Mutation (SNP) | VAF 139/301 reads (46%) | catalogued as COSV101267335, COSV101267663; called by muse, mutect2, varscan2
- TCL1A | c.113C>T p.T38I | Missense Mutation (SNP) | VAF 125/226 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs201228671, COSV68085105, COSV68085114, COSV68085683; called by muse, mutect2, varscan2
- TEX15 | c.4438A>G p.T1480A (on ENST00000256246; = p.T1863A on NM_001350162.2) | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as rs770682375; called by muse, mutect2, varscan2
- TGFBR1 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 104/207 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1564161322, CM165735, COSV66624829; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMEM52B | c.10C>T p.R4* | Nonsense Mutation (SNP) | VAF 135/283 reads (48%) | catalogued as rs769702735, COSV100046501; called by muse, mutect2, varscan2
- TRAM2 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); catalogued as rs189107930; called by muse, mutect2, varscan2
- TRPC7 | c.359G>T p.R120L | Missense Mutation (SNP) | VAF 111/207 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV61454688; called by muse, mutect2, varscan2
- TTN | c.55549G>A p.G18517S (on ENST00000591111; = p.G11093S on NM_003319.4) | Missense Mutation (SNP) | VAF 108/215 reads (50%) | PolyPhen probably damaging (0.999); catalogued as rs375009570, COSV100625963; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUSC3 | c.395A>C p.D132A | Missense Mutation (SNP) | VAF 57/117 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101142547; called by muse, mutect2, varscan2
- UNC13A | c.4171G>A p.V1391I | Missense Mutation (SNP) | VAF 60/125 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as rs777663703; called by muse, mutect2, varscan2
- UNC80 | c.5444G>A p.R1815H | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); catalogued as rs761112873, COSV55887142; called by muse, mutect2, varscan2
- UPF2 | c.3383G>A p.R1128Q | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs979564728, COSV62660845; called by muse, mutect2, varscan2
- XKR7 | c.1258G>A p.V420I | Missense Mutation (SNP) | VAF 138/294 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.269); catalogued as rs538702175, COSV73813171, COSV73813507; called by muse, mutect2, varscan2
- YIF1A | c.285dup p.A96Cfs*30 | Frame Shift Ins (INS) | VAF 30/62 reads (48%) | catalogued as rs752032166; called by mutect2, varscan2
- ZBTB7A | c.118G>T p.V40L | Missense Mutation (SNP) | VAF 113/223 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as COSV100475826; called by muse, mutect2, varscan2
- ZFP36L1 | c.57+1G>C p.X19_splice | Splice Site (SNP) | VAF 26/76 reads (34%) | catalogued as COSV60544075; called by muse, mutect2, varscan2
- ZMYM5 | c.1775A>G p.Y592C | Missense Mutation (SNP) | VAF 59/128 reads (46%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.993); catalogued as COSV61989061; called by muse, mutect2, varscan2
- ZNF462 | c.6352G>A p.V2118I | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.365); catalogued as rs753969030, COSV52932673; called by muse, mutect2, varscan2
- ACTR10 | c.72T>A p.F24L | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- ADAMTS3 | c.2425-1G>T p.X809_splice | Splice Site (SNP) | VAF 94/183 reads (51%) | called by muse, mutect2, varscan2
- ALDH7A1 | c.298A>C p.K100Q | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AMER1 | c.2710A>T p.M904L | Missense Mutation (SNP) | VAF 79/165 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD11 | c.2644A>T p.K882* | Nonsense Mutation (SNP) | VAF 100/205 reads (49%) | called by muse, mutect2, varscan2
- ANO3 | c.1287A>G p.V429= | Splice Region (SNP) | VAF 41/93 reads (44%) | called by muse, mutect2, varscan2
- ARMCX1 | c.68G>C p.C23S | Missense Mutation (SNP) | VAF 75/151 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ASPM | c.7744dup p.I2582Nfs*7 | Frame Shift Ins (INS) | VAF 89/121 reads (74%) | called by mutect2, pindel, varscan2
- ATP2C1 | c.2299A>G p.K767E | Missense Mutation (SNP) | VAF 76/128 reads (59%) | SIFT tolerated (0.24); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- B3GLCT | c.852A>G p.I284M | Missense Mutation (SNP) | VAF 44/44 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, varscan2
- B3GLCT | c.863A>G p.K288R | Missense Mutation (SNP) | VAF 49/49 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.465); called by muse, varscan2
- BDP1 | c.3975G>T p.E1325D | Missense Mutation (SNP) | VAF 107/225 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- BRWD3 | c.4754T>C p.M1585T | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); called by muse, varscan2
- CADPS2 | c.4C>A p.L2M | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- CD22 | c.2061_2064dup p.A689Sfs*48 | Frame Shift Ins (INS) | VAF 31/71 reads (44%) | called by mutect2, pindel, varscan2
- CDKL5 | c.1378C>A p.P460T | Missense Mutation (SNP) | VAF 69/158 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- CELSR3 | c.8113G>T p.A2705S | Missense Mutation (SNP) | VAF 71/129 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- CENPH | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 82/195 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP47 | c.4492C>T p.H1498Y | Missense Mutation (SNP) | VAF 87/187 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CFTR | c.979C>A p.L327I | Missense Mutation (SNP) | VAF 75/166 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.072); called by muse, varscan2
- CHRM2 | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- CHRND | c.214A>C p.T72P | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CKMT2 | c.249C>G p.N83K | Missense Mutation (SNP) | VAF 62/154 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- CPSF1 | c.3349del p.L1117Sfs*24 | Frame Shift Del (DEL) | VAF 76/254 reads (30%) | called by mutect2, varscan2
- CRISPLD1 | c.101A>C p.K34T | Missense Mutation (SNP) | VAF 83/177 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DAPK1 | c.3964C>T p.P1322S | Missense Mutation (SNP) | VAF 150/292 reads (51%) | SIFT tolerated (0.22); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- DCAF4L1 | c.1115T>C p.L372P | Missense Mutation (SNP) | VAF 130/283 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- DIPK2A | c.283C>T p.Q95* | Nonsense Mutation (SNP) | VAF 80/162 reads (49%) | called by muse, mutect2, varscan2
- DIS3 | c.654+1G>C p.X218_splice | Splice Site (SNP) | VAF 32/69 reads (46%) | called by muse, mutect2, varscan2
- DKK1 | c.700T>G p.F234V | Missense Mutation (SNP) | VAF 167/355 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DNAAF6 | c.-2T>G | Splice Region (SNP) | VAF 78/154 reads (51%) | called by muse, mutect2, varscan2
- DUSP2 | c.374T>A p.V125E | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- EPHA7 | c.2123T>C p.M708T | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EXOSC1 | c.345G>A p.K115= | Splice Region (SNP) | VAF 102/243 reads (42%) | called by muse, mutect2, varscan2
- EYA1 | c.1225T>G p.F409V | Missense Mutation (SNP) | VAF 99/195 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- FAM135B | c.2415C>A p.S805R | Missense Mutation (SNP) | VAF 132/206 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM83B | c.2641G>C p.A881P | Missense Mutation (SNP) | VAF 116/247 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GALNT16 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 80/155 reads (52%) | SIFT tolerated (0.41); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GJD2 | c.959_960del p.Y320Cfs*8 | Frame Shift Del (DEL) | VAF 20/44 reads (45%) | called by mutect2, pindel, varscan2
- GPX1 | c.344G>T p.C115F | Missense Mutation (SNP) | VAF 65/142 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- HTATSF1 | c.855T>G p.N285K | Missense Mutation (SNP) | VAF 105/213 reads (49%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- HTATSF1 | c.1776A>C p.L592F | Missense Mutation (SNP) | VAF 115/205 reads (56%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGHD1-26 | c.5T>G p.I2R | Missense Mutation (SNP) | VAF 14/14 reads (100%) | PolyPhen possibly damaging (0.845); called by muse, mutect2
- IGHD6-25 | c.6T>G p.Y2* | Nonsense Mutation (SNP) | VAF 67/67 reads (100%) | called by muse, mutect2, varscan2
- IGHG1 | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 32/33 reads (97%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- IGKV1-5 | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.108); called by muse, varscan2
- IGKV1-8 | c.227G>C p.S76T | Missense Mutation (SNP) | VAF 119/238 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- IGLV4-3 | c.170A>T p.Q57L | Missense Mutation (SNP) | VAF 90/186 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, varscan2
- IGLV4-69 | c.213C>G p.N71K | Missense Mutation (SNP) | VAF 88/166 reads (53%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- ILRUN | c.314-2A>G p.X105_splice | Splice Site (SNP) | VAF 17/40 reads (43%) | called by mutect2, varscan2
- IQCD | c.556A>G p.S186G | Missense Mutation (SNP) | VAF 103/192 reads (54%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- JRKL | c.113G>C p.G38A | Missense Mutation (SNP) | VAF 67/129 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLHL34 | c.821G>T p.S274I | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- LDAH | c.653A>T p.N218I | Missense Mutation (SNP) | VAF 148/329 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- LNPK | c.1018G>A p.G340R | Missense Mutation (SNP) | VAF 99/203 reads (49%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- LYPLA2 | c.301G>T p.A101S | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- METAP2 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MFN1 | c.1330-1G>A p.X444_splice | Splice Site (SNP) | VAF 56/125 reads (45%) | called by muse, mutect2, varscan2
- MFN2 | c.2198T>C p.L733P | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- NEDD4L | c.2506C>T p.P836S (on ENST00000400345 / NM_001144967.3; = p.P816S on NM_015277.6) | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- NLRP6 | c.1838A>C p.E613A | Missense Mutation (SNP) | VAF 72/142 reads (51%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- NUP210L | c.866T>A p.L289Q | Missense Mutation (SNP) | VAF 161/162 reads (99%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OCM2 | c.196T>G p.F66V | Missense Mutation (SNP) | VAF 60/153 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- OR2T27 | c.123C>A p.S41R | Missense Mutation (SNP) | VAF 103/201 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- OR51A7 | c.34T>C p.F12L | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR5D13 | c.95T>G p.V32G | Missense Mutation (SNP) | VAF 87/190 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PCDH10 | c.2744A>C p.D915A | Missense Mutation (SNP) | VAF 64/147 reads (44%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PCDHB16 | c.2218A>C p.S740R | Missense Mutation (SNP) | VAF 87/167 reads (52%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PHKA2 | c.3201G>C p.W1067C | Missense Mutation (SNP) | VAF 67/127 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PLEKHA1 | c.-20-7T>G | Splice Region (SNP) | VAF 140/278 reads (50%) | called by muse, varscan2
- PPAN-P2RY11 | c.1082A>G p.E361G | Missense Mutation (SNP) | VAF 62/135 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRRC2C | c.6767G>A p.R2256H (on ENST00000367742; = p.R2254H on NM_015172.4) | Missense Mutation (SNP) | VAF 168/170 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RAB41 | c.265G>A p.G89S (on ENST00000374473 / NM_001363807.1; = p.G88S on NM_001032726.3) | Missense Mutation (SNP) | VAF 67/143 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RFTN1 | c.746T>C p.L249P | Missense Mutation (SNP) | VAF 81/172 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- RIPOR2 | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 110/229 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- RPS15 | c.92A>G p.E31G | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- SEC23IP | c.1092A>C p.E364D | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SELP | c.301_302delinsA p.W101Rfs*51 | Frame Shift Del (DEL) | VAF 49/204 reads (24%) | called by pindel, varscan2*
- SEMA5A | c.3155A>C p.N1052T | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- SLITRK1 | c.991A>T p.R331W | Missense Mutation (SNP) | VAF 55/106 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- SPTLC3 | c.323A>G p.Q108R | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SRCAP | c.4385C>T p.P1462L | Missense Mutation (SNP) | VAF 216/459 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, varscan2
- STOX1 | c.1388G>T p.R463I | Missense Mutation (SNP) | VAF 123/234 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- TENT5D | c.303A>T p.K101N | Missense Mutation (SNP) | VAF 94/189 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMC1 | c.2245G>A p.A749T | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- TNFAIP6 | c.424C>G p.P142A | Missense Mutation (SNP) | VAF 80/160 reads (50%) | SIFT tolerated (0.51); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- VCPIP1 | c.281T>A p.V94E | Missense Mutation (SNP) | VAF 82/175 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZBTB5 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 182/268 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- ZNF462 | c.937C>T p.P313S | Missense Mutation (SNP) | VAF 76/151 reads (50%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF532 | c.824C>A p.A275E | Missense Mutation (SNP) | VAF 57/145 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- ZNF630 | c.1178A>G p.H393R | Missense Mutation (SNP) | VAF 83/161 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- ZNF646 | c.1447C>T p.H483Y | Missense Mutation (SNP) | VAF 115/252 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ALPL | c.1353C>T p.H451= | Silent (SNP) | VAF 112/211 reads (53%) | catalogued as rs377110098; called by muse, mutect2, varscan2
- ARMC4 | c.861A>G p.K287= | Silent (SNP) | VAF 36/82 reads (44%) | catalogued as COSV53468388; called by muse, mutect2, varscan2
- C6orf226 | c.81G>T p.L27= | Silent (SNP) | VAF 57/100 reads (57%) | called by muse, mutect2, varscan2
- CARMIL1 | c.3606C>T p.G1202= | Silent (SNP) | VAF 57/113 reads (50%) | catalogued as rs764642099; called by muse, mutect2, varscan2
- COL3A1 | c.186C>T p.C62= | Silent (SNP) | VAF 132/275 reads (48%) | catalogued as rs764749176, COSV58593556; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNER | c.1830T>C p.G610= | Silent (SNP) | VAF 49/100 reads (49%) | called by muse, mutect2, varscan2
- DSCAM | c.1044C>T p.Y348= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as rs778177192; called by muse, mutect2, varscan2
- DUSP2 | c.375G>A p.V125= | Silent (SNP) | VAF 64/118 reads (54%) | catalogued as rs1005029732; called by muse, mutect2, varscan2
- EGFLAM | c.2361C>T p.P787= | Silent (SNP) | VAF 66/140 reads (47%) | catalogued as COSV100380853; called by muse, mutect2, varscan2
- EPS15L1 | c.1668G>A p.E556= | Silent (SNP) | VAF 45/98 reads (46%) | called by muse, mutect2, varscan2
- GAB4 | c.105G>A p.T35= | Silent (SNP) | VAF 36/85 reads (42%) | called by muse, mutect2, varscan2
- GLUD2 | c.1221G>T p.G407= | Silent (SNP) | VAF 59/140 reads (42%) | called by muse, mutect2, varscan2
- IGLV3-1 | c.333C>T p.S111= | Silent (SNP) | VAF 65/174 reads (37%) | catalogued as rs151220536; called by muse, varscan2
- IL1A | c.414C>T p.D138= | Silent (SNP) | VAF 93/184 reads (51%) | catalogued as rs376957964, COSV99641326; called by muse, mutect2, varscan2
- KIAA1210 | c.2937G>A p.K979= | Silent (SNP) | VAF 82/149 reads (55%) | called by muse, mutect2, varscan2
- LRP2 | c.11451C>T p.C3817= | Silent (SNP) | VAF 59/116 reads (51%) | catalogued as rs745376364, COSV55565185; called by muse, mutect2, varscan2
- LRRN4 | c.723G>A p.L241= | Silent (SNP) | VAF 45/89 reads (51%) | called by muse, mutect2, varscan2
- MEA1 | c.141G>A p.G47= | Silent (SNP) | VAF 77/163 reads (47%) | catalogued as rs771725871; called by muse, mutect2, varscan2
- MKX | c.393C>T p.T131= | Silent (SNP) | VAF 113/230 reads (49%) | catalogued as rs760522501; called by muse, mutect2, varscan2
- MUC17 | c.10935A>C p.T3645= | Silent (SNP) | VAF 127/282 reads (45%) | called by muse, mutect2, varscan2
- MUC5B | c.9024C>T p.S3008= | Silent (SNP) | VAF 82/180 reads (46%) | catalogued as COSV71591901; called by muse, mutect2, varscan2
- NKX1-1 | c.795G>A p.A265= | Silent (SNP) | VAF 16/29 reads (55%) | catalogued as rs758494888; called by muse, mutect2, varscan2
- NPAS3 | c.1728G>A p.T576= (on ENST00000356141 / NM_001164749.2; = p.T544= on NM_022123.3) | Silent (SNP) | VAF 103/201 reads (51%) | called by muse, mutect2, varscan2
- NXPE1 | c.1143C>A p.I381= (on ENST00000424269; = p.I239= on NM_152315.5) | Silent (SNP) | VAF 64/141 reads (45%) | catalogued as rs765334619; called by muse, mutect2, varscan2
- OBSL1 | c.186G>A p.A62= | Silent (SNP) | VAF 27/51 reads (53%) | called by muse, mutect2, varscan2
- ODF4 | c.708G>A p.T236= | Silent (SNP) | VAF 88/189 reads (47%) | catalogued as rs138113934; called by muse, mutect2, varscan2
- PCDH17 | c.2454G>A p.P818= | Silent (SNP) | VAF 55/55 reads (100%) | called by muse, varscan2
- PDE2A | c.1497G>A p.T499= | Silent (SNP) | VAF 61/132 reads (46%) | catalogued as rs899573405; called by muse, mutect2, varscan2
- PEX12 | c.300T>C p.S100= | Silent (SNP) | VAF 101/263 reads (38%) | called by muse, mutect2, varscan2
- PI15 | c.300G>A p.S100= | Silent (SNP) | VAF 106/230 reads (46%) | catalogued as rs1423685861, COSV52640862, COSV52644839; called by muse, mutect2, varscan2
- PPP1R9A | c.1839G>A p.Q613= | Silent (SNP) | VAF 54/115 reads (47%) | called by muse, mutect2, varscan2
- PRKCG | c.1425C>A p.G475= | Silent (SNP) | VAF 100/215 reads (47%) | called by muse, mutect2, varscan2
- PRRT1 | c.402G>A p.P134= | Silent (SNP) | VAF 7/27 reads (26%) | called by muse, mutect2, varscan2
- PTGER2 | c.342C>T p.F114= | Silent (SNP) | VAF 151/290 reads (52%) | catalogued as rs1397436185; called by muse, mutect2, varscan2
- RNF213 | c.15057C>T p.S5019= | Silent (SNP) | VAF 72/178 reads (40%) | catalogued as rs767371073, COSV60410534; called by muse, mutect2, varscan2
- SEC24D | c.99G>C p.S33= | Silent (SNP) | VAF 93/199 reads (47%) | called by muse, mutect2, varscan2
- SLC37A2 | c.1476G>C p.L492= | Silent (SNP) | VAF 96/212 reads (45%) | called by muse, mutect2, varscan2
- SLC39A7 | c.15G>A p.L5= | Silent (SNP) | VAF 52/134 reads (39%) | called by muse, mutect2, varscan2
- TIAM1 | c.1242C>T p.S414= | Silent (SNP) | VAF 70/157 reads (45%) | catalogued as rs765934871, COSV54557443; called by muse, mutect2, varscan2
- TPBGL | c.1023C>T p.R341= | Silent (SNP) | VAF 63/121 reads (52%) | called by muse, mutect2, varscan2
- TPRX1 | c.186C>A p.I62= | Silent (SNP) | VAF 60/127 reads (47%) | catalogued as COSV100445973; called by muse, mutect2, varscan2
- TRPC1 | c.1287G>C p.L429= (on ENST00000476941 / NM_001251845.2; = p.L395= on NM_003304.4) | Silent (SNP) | VAF 25/45 reads (56%) | catalogued as rs1242265471; called by muse, mutect2, varscan2
- UBQLN3 | c.999T>C p.F333= | Silent (SNP) | VAF 66/118 reads (56%) | catalogued as rs753601730; called by muse, mutect2, varscan2
- VWCE | c.1812G>A p.R604= | Silent (SNP) | VAF 43/67 reads (64%) | called by muse, mutect2, varscan2
- ZXDC | c.1752C>T p.L584= | Silent (SNP) | VAF 72/158 reads (46%) | catalogued as rs573894842, COSV60448854; called by muse, mutect2, varscan2
- ABI3BP | c.1064-312T>A | Intron (SNP) | VAF 10/16 reads (63%) | catalogued as rs1035283810; called by muse, mutect2, varscan2
- AC024651.2 | chr15:97874371 A>C | 5'Flank (SNP) | VAF 24/40 reads (60%) | called by muse, mutect2, varscan2
- AC092718.9 | chr16:81148334 C>A | 5'Flank (SNP) | VAF 59/113 reads (52%) | called by muse, mutect2, varscan2
- AC099654.2 | n.1342T>C | RNA (SNP) | VAF 12/19 reads (63%) | called by muse, mutect2, varscan2
- AC112695.1 | n.382T>C | RNA (SNP) | VAF 22/43 reads (51%) | called by muse, mutect2, varscan2
- ADAM20P1 | n.1319C>T | RNA (SNP) | VAF 84/164 reads (51%) | called by muse, mutect2, varscan2
- ADAMTS18 | c.-224G>A | 5'UTR (SNP) | VAF 39/85 reads (46%) | catalogued as rs1019240492; called by muse, mutect2, varscan2
- ADCY2 | c.*2479T>C | 3'UTR (SNP) | VAF 40/87 reads (46%) | called by muse, mutect2, varscan2
- ADGRL4 | c.*869G>T | 3'UTR (SNP) | VAF 21/22 reads (95%) | called by muse, mutect2, varscan2
- ADNP | chr20:50890164 A>G | 3'Flank (SNP) | VAF 25/50 reads (50%) | catalogued as rs1219862412; called by muse, mutect2, varscan2
- AGAP1 | c.*1944del | 3'UTR (DEL) | VAF 28/73 reads (38%) | catalogued as rs1289136451; called by mutect2, pindel, varscan2
- AGO4 | c.*4086A>T | 3'UTR (SNP) | VAF 33/59 reads (56%) | called by muse, mutect2, varscan2
- ANKRD13B | c.422-30A>G | Intron (SNP) | VAF 51/119 reads (43%) | called by muse, mutect2, varscan2
- ANKS1B | c.3672+7031G>A | Intron (SNP) | VAF 47/116 reads (41%) | called by muse, mutect2, varscan2
- AQP7 | c.406+54A>T | Intron (SNP) | VAF 25/77 reads (32%) | called by muse, mutect2, varscan2
- AR | c.1885+8857T>C | Intron (SNP) | VAF 35/82 reads (43%) | called by muse, mutect2, varscan2
- AR | c.*5565C>A | 3'UTR (SNP) | VAF 25/64 reads (39%) | catalogued as rs1486034191; called by muse, mutect2, varscan2
- ARFGEF2 | c.*919T>C | 3'UTR (SNP) | VAF 24/51 reads (47%) | called by muse, mutect2, varscan2
- ARID5B | c.*1317G>A | 3'UTR (SNP) | VAF 35/65 reads (54%) | called by muse, mutect2, varscan2
- ART4 | c.-104del | 5'UTR (DEL) | VAF 41/89 reads (46%) | called by mutect2, varscan2
- ATP5F1E | c.*4-516G>A | Intron (SNP) | VAF 24/54 reads (44%) | called by muse, mutect2, varscan2
- B4GALT6 | chr18:31622368 A>C | 3'Flank (SNP) | VAF 45/104 reads (43%) | called by muse, mutect2, varscan2
- BAALC | chr8:103228810 T>C | 3'Flank (SNP) | VAF 89/166 reads (54%) | called by muse, mutect2, varscan2
- BCAP31 | c.602-148G>T | Intron (SNP) | VAF 5/11 reads (45%) | called by muse, mutect2, varscan2
- BCL11B | c.*1868G>A | 3'UTR (SNP) | VAF 57/110 reads (52%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021517 G>C | 5'Flank (SNP) | VAF 102/217 reads (47%) | catalogued as COSV55846497, COSV55849856; called by muse, mutect2, varscan2
- BDNF | c.*254G>A | 3'UTR (SNP) | VAF 52/106 reads (49%) | called by muse, mutect2, varscan2
- BMPR1B | chr4:95156403 G>C | 3'Flank (SNP) | VAF 20/41 reads (49%) | called by muse, mutect2, varscan2
- BMT2 | c.*2448T>C | 3'UTR (SNP) | VAF 50/113 reads (44%) | called by muse, mutect2, varscan2
- C14orf132 | chr14:96088559 G>A | 3'Flank (SNP) | VAF 25/152 reads (16%) | called by muse, mutect2, varscan2
- C2orf72 | c.*376G>A | 3'UTR (SNP) | VAF 63/135 reads (47%) | called by muse, mutect2, varscan2
- C6orf201 | c.-234C>T | 5'UTR (SNP) | VAF 37/67 reads (55%) | called by muse, mutect2, varscan2
- CACHD1 | c.*171A>G | 3'UTR (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2, varscan2
- CACNA2D1 | chr7:81949947 A>C | 3'Flank (SNP) | VAF 37/75 reads (49%) | called by muse, mutect2, varscan2
- CACUL1 | c.*1044A>T | 3'UTR (SNP) | VAF 46/81 reads (57%) | called by muse, mutect2, varscan2
- CALCOCO1 | c.*603dup | 3'UTR (INS) | VAF 25/61 reads (41%) | catalogued as rs889484981; called by mutect2, pindel, varscan2
- CALD1 | c.*1352T>C | 3'UTR (SNP) | VAF 41/73 reads (56%) | called by muse, mutect2, varscan2
- CALN1 | c.*5360T>C | 3'UTR (SNP) | VAF 8/16 reads (50%) | called by muse, mutect2, varscan2
- CASKIN1 | c.*1208C>T | 3'UTR (SNP) | VAF 39/63 reads (62%) | called by muse, mutect2, varscan2
- CBLIF | c.371-22A>C | Intron (SNP) | VAF 24/57 reads (42%) | called by muse, mutect2, varscan2
- CCM2 | c.746-1056G>T | Intron (SNP) | VAF 15/31 reads (48%) | called by muse, mutect2, varscan2
- CD177P1 | n.22C>A | RNA (SNP) | VAF 55/123 reads (45%) | called by muse, mutect2, varscan2
- CD27 | c.-88A>G | 5'UTR (SNP) | VAF 33/70 reads (47%) | called by muse, mutect2, varscan2
- CD7 | c.613-60G>A | Intron (SNP) | VAF 45/111 reads (41%) | called by muse, mutect2, varscan2
- CD81 | c.561+22G>A | Intron (SNP) | VAF 48/99 reads (48%) | catalogued as rs34403950, COSV55133961; called by muse, mutect2, varscan2
- CDH8 | c.*5924A>G | 3'UTR (SNP) | VAF 30/57 reads (53%) | called by muse, varscan2
- CEP78 | c.*6798G>C | 3'UTR (SNP) | VAF 97/156 reads (62%) | called by muse, mutect2, varscan2
- CFAP74 | c.2176+307G>C | Intron (SNP) | VAF 61/117 reads (52%) | called by muse, mutect2, varscan2
- CNKSR2 | c.*532A>G | 3'UTR (SNP) | VAF 28/53 reads (53%) | called by muse, mutect2, varscan2
- CNKSR2 | c.*2001T>A | 3'UTR (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
- CNTN1 | c.1805-9225T>A | Intron (SNP) | VAF 96/179 reads (54%) | catalogued as rs929875055; called by muse, mutect2, varscan2
- COL6A1 | c.*115dup | 3'UTR (INS) | VAF 39/84 reads (46%) | catalogued as rs889031226; called by mutect2, varscan2
- COPE | c.444-165_444-162dup | Intron (INS) | VAF 60/126 reads (48%) | called by mutect2, pindel, varscan2
- CPNE3 | c.732+72T>C | Intron (SNP) | VAF 21/52 reads (40%) | called by muse, varscan2
- CPS1 | c.*685G>A | 3'UTR (SNP) | VAF 14/36 reads (39%) | catalogued as rs1218134492; called by muse, mutect2, varscan2
- CRELD2 | c.1009+127G>A | Intron (SNP) | VAF 12/25 reads (48%) | catalogued as rs768664834; called by muse, mutect2, varscan2
- CUBN | c.593+596T>A | Intron (SNP) | VAF 28/68 reads (41%) | called by muse, mutect2
- CXCL1 | c.*395C>T | 3'UTR (SNP) | VAF 24/50 reads (48%) | called by muse, mutect2, varscan2
- CYCS | c.*883A>G | 3'UTR (SNP) | VAF 19/47 reads (40%) | called by muse, mutect2
- DACH2 | c.1751-1737G>T | Intron (SNP) | VAF 30/61 reads (49%) | called by muse, mutect2, varscan2
- DDX31 | chr9:132593859 G>A | 3'Flank (SNP) | VAF 56/141 reads (40%) | called by muse, mutect2, varscan2
- DGKB | c.2307+637C>A | Intron (SNP) | VAF 51/99 reads (52%) | catalogued as COSV51771915; called by muse, mutect2, varscan2
- DLX1 | c.*1169A>C | 3'UTR (SNP) | VAF 53/108 reads (49%) | called by muse, mutect2, varscan2
- DMRTA1 | c.-152C>A | 5'UTR (SNP) | VAF 81/118 reads (69%) | called by muse, mutect2, varscan2
- DOK6 | c.-15C>T | 5'UTR (SNP) | VAF 78/145 reads (54%) | called by muse, mutect2, varscan2
- DPPA4 | c.*1209C>A | 3'UTR (SNP) | VAF 59/106 reads (56%) | called by muse, mutect2, varscan2
- DPYSL3 | c.*149C>A | 3'UTR (SNP) | VAF 44/95 reads (46%) | catalogued as rs929679125; called by muse, mutect2, varscan2
- DR1 | chr1:93361750 A>G | 3'Flank (SNP) | VAF 27/68 reads (40%) | called by muse, mutect2, varscan2
- DTX1 | c.-353C>T | 5'UTR (SNP) | VAF 34/71 reads (48%) | catalogued as rs1173099979; called by muse, mutect2, varscan2
- DTX4 | c.*1627T>C | 3'UTR (SNP) | VAF 4/8 reads (50%) | called by muse, mutect2
- EEF1A1 | c.-31+176G>A | Intron (SNP) | VAF 78/137 reads (57%) | called by muse, mutect2, varscan2
- EGR1 | c.-126G>A | 5'UTR (SNP) | VAF 17/38 reads (45%) | catalogued as COSV53520591; called by muse, mutect2, varscan2
- EMX1 | chr2:72916363 C>T | 5'Flank (SNP) | VAF 57/105 reads (54%) | called by muse, mutect2, varscan2
- EXOC4 | c.*86A>C | 3'UTR (SNP) | VAF 63/113 reads (56%) | called by muse, mutect2, varscan2
- FAM110C | c.*353T>A | 3'UTR (SNP) | VAF 30/53 reads (57%) | catalogued as rs896914654; called by muse, mutect2, varscan2
- FAM120C | c.*1699G>T | 3'UTR (SNP) | VAF 23/36 reads (64%) | called by muse, mutect2, varscan2
- FAM122B | c.-694G>T | 5'UTR (SNP) | VAF 25/46 reads (54%) | called by muse, mutect2, varscan2
- FAM13B | c.2095-13dup | Intron (INS) | VAF 9/30 reads (30%) | catalogued as rs762099662; called by mutect2, varscan2
- FAM161B | c.*5T>C | 3'UTR (SNP) | VAF 176/363 reads (48%) | called by muse, mutect2, varscan2
- FER | c.*4634A>G | 3'UTR (SNP) | VAF 43/44 reads (98%) | called by muse, mutect2, varscan2
- FERMT1 | c.*1472G>A | 3'UTR (SNP) | VAF 63/148 reads (43%) | catalogued as rs41282954; ClinVar: uncertain significance; called by muse, mutect2
- FO681492.1 | c.-127T>C | 5'UTR (SNP) | VAF 7/22 reads (32%) | called by muse, mutect2, varscan2
- FOXE1 | c.-337C>T | 5'UTR (SNP) | VAF 10/242 reads (4%) | called by muse, mutect2
- FUT9 | c.*1150C>T | 3'UTR (SNP) | VAF 37/85 reads (44%) | called by muse, mutect2, varscan2
- GABBR1 | c.*645C>T | 3'UTR (SNP) | VAF 25/56 reads (45%) | catalogued as rs550602125; called by muse, mutect2, varscan2
- GDI1 | c.820-64C>T | Intron (SNP) | VAF 17/35 reads (49%) | catalogued as rs782480279; called by muse, mutect2, varscan2
- GNG12 | c.*589del | 3'UTR (DEL) | VAF 25/61 reads (41%) | called by mutect2, pindel, varscan2
- GNG5P2 | n.31A>G | RNA (SNP) | VAF 96/188 reads (51%) | called by muse, mutect2, varscan2
- GOLGA8B | c.*303C>A | 3'UTR (SNP) | VAF 42/88 reads (48%) | called by muse, mutect2
- GPAT4 | c.*1173T>A | 3'UTR (SNP) | VAF 54/109 reads (50%) | called by muse, mutect2, varscan2
- GPC6 | c.-93G>A | 5'UTR (SNP) | VAF 59/99 reads (60%) | called by muse, mutect2, varscan2
- GPR3 | c.*773C>T | 3'UTR (SNP) | VAF 63/132 reads (48%) | catalogued as COSV64994807; called by muse, mutect2, varscan2
- GRIA2 | c.*3+73A>C | Intron (SNP) | VAF 46/83 reads (55%) | called by muse, mutect2, varscan2
- GSKIP | c.*1291del | 3'UTR (DEL) | VAF 54/134 reads (40%) | called by mutect2, pindel, varscan2
- HCN4 | c.-598C>T | 5'UTR (SNP) | VAF 22/37 reads (59%) | catalogued as rs1031301334; called by muse, mutect2, varscan2
- HEATR1 | c.*1680G>T | 3'UTR (SNP) | VAF 83/83 reads (100%) | called by muse, mutect2, varscan2
- HEATR4 | c.*63T>A | 3'UTR (SNP) | VAF 165/344 reads (48%) | called by muse, mutect2, varscan2
- HSP90AA4P | n.910T>C | RNA (SNP) | VAF 64/111 reads (58%) | called by muse, mutect2, varscan2
- HSPA12A | c.*2106C>T | 3'UTR (SNP) | VAF 45/92 reads (49%) | catalogued as rs1361534470, COSV100979901; called by muse, mutect2, varscan2
- IDS | c.1007-149T>C | Intron (SNP) | VAF 114/228 reads (50%) | called by muse, mutect2, varscan2
- IGLL5 | c.-8G>A | 5'UTR (SNP) | VAF 47/86 reads (55%) | catalogued as rs564804719; called by muse, mutect2, varscan2
- ING1 | chr13:110713258 G>A | 5'Flank (SNP) | VAF 58/134 reads (43%) | called by muse, mutect2, varscan2
- IPMK | c.*3514T>C | 3'UTR (SNP) | VAF 188/392 reads (48%) | catalogued as rs967443505; called by muse, mutect2, varscan2
- IRAG1 | c.*548dup | 3'UTR (INS) | VAF 12/44 reads (27%) | called by mutect2, pindel, varscan2
- IRX2 | c.*718A>C | 3'UTR (SNP) | VAF 16/33 reads (48%) | called by muse, mutect2, varscan2
- KCNC2 | c.*956T>G | 3'UTR (SNP) | VAF 47/99 reads (47%) | called by muse, mutect2, varscan2
- KCTD3 | c.-94C>T | 5'UTR (SNP) | VAF 23/23 reads (100%) | called by muse, mutect2, varscan2
- KCTD9 | c.*1149A>G | 3'UTR (SNP) | VAF 119/245 reads (49%) | catalogued as rs554769524; called by muse, mutect2, varscan2
- KIAA1210 | c.*371T>C | 3'UTR (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2, varscan2
- KIFC2 | chr8:144474136 T>C | 3'Flank (SNP) | VAF 42/141 reads (30%) | called by muse, mutect2, varscan2
- KLC1 | c.1650+6490G>A | Intron (SNP) | VAF 49/93 reads (53%) | catalogued as rs1408143861; called by muse, mutect2, varscan2
- KMT2A | c.432+773A>G | Intron (SNP) | VAF 11/25 reads (44%) | catalogued as rs554229477; called by muse, mutect2, varscan2
- KRTAP4-3 | c.*88T>C | 3'UTR (SNP) | VAF 88/177 reads (50%) | called by muse, mutect2, varscan2
- LAMP2 | c.1093+4735G>C | Intron (SNP) | VAF 35/68 reads (51%) | called by muse, mutect2, varscan2
- LIN28B | c.*1682T>C | 3'UTR (SNP) | VAF 28/66 reads (42%) | called by muse, mutect2, varscan2
- LINC01299 | n.1011C>A | RNA (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- LINC01537 | n.82A>G | RNA (SNP) | VAF 36/100 reads (36%) | catalogued as rs1262376388; called by muse, mutect2, varscan2
- LMO7DN | n.344C>T | RNA (SNP) | VAF 10/23 reads (43%) | catalogued as rs1401419745; called by muse, mutect2, varscan2
- LRATD1 | c.*1479C>A | 3'UTR (SNP) | VAF 34/72 reads (47%) | catalogued as rs1457011851; called by muse, mutect2, varscan2
- LRATD1 | c.*2926G>A | 3'UTR (SNP) | VAF 28/65 reads (43%) | catalogued as rs577736519; called by muse, mutect2, varscan2
- LTB | c.208+12C>T | Intron (SNP) | VAF 151/293 reads (52%) | catalogued as rs373114079; called by muse, varscan2
- LTB | c.163-149C>T | Intron (SNP) | VAF 110/213 reads (52%) | catalogued as rs149833445, COSV53000289, COSV53002609; called by muse, varscan2
- LUZP2 | c.*1264G>A | 3'UTR (SNP) | VAF 38/82 reads (46%) | called by muse, mutect2, varscan2
- MAGEC3 | c.910-591G>T | Intron (SNP) | VAF 56/114 reads (49%) | catalogued as rs959456925; called by muse, mutect2, varscan2
- MAGEC3 | c.910-590G>A | Intron (SNP) | VAF 56/112 reads (50%) | called by muse, mutect2, varscan2
- MAGI3 | c.*263G>A | 3'UTR (SNP) | VAF 28/71 reads (39%) | catalogued as rs567560945; called by muse, mutect2, varscan2
- MAP1A | c.-136C>T | 5'UTR (SNP) | VAF 102/198 reads (52%) | called by muse, mutect2, varscan2
- MAP2 | c.*1158T>A | 3'UTR (SNP) | VAF 34/62 reads (55%) | called by muse, mutect2, varscan2
- MAP2K1 | c.*825A>C | 3'UTR (SNP) | VAF 62/115 reads (54%) | called by muse, mutect2, varscan2
- MAP4K5 | c.*995T>C | 3'UTR (SNP) | VAF 51/109 reads (47%) | called by muse, mutect2, varscan2
- MAPK13 | c.*587G>A | 3'UTR (SNP) | VAF 30/57 reads (53%) | called by muse, mutect2, varscan2
- MAPK6 | c.-129C>T | 5'UTR (SNP) | VAF 106/206 reads (51%) | called by muse, mutect2, varscan2
- MASP1 | c.1303+5258T>C | Intron (SNP) | VAF 150/284 reads (53%) | called by muse, mutect2, varscan2
- MAST4 | c.*733T>C | 3'UTR (SNP) | VAF 42/82 reads (51%) | called by muse, mutect2, varscan2
- MEMO1 | c.*98T>A | 3'UTR (SNP) | VAF 112/253 reads (44%) | called by muse, mutect2, varscan2
- MICOS10 | c.64+11437_64+11438del | Intron (DEL) | VAF 84/191 reads (44%) | called by mutect2, pindel, varscan2
- MIDEAS | c.*3909C>T | 3'UTR (SNP) | VAF 38/71 reads (54%) | called by muse, mutect2, varscan2
- MINDY4 | c.*9T>A | 3'UTR (SNP) | VAF 119/235 reads (51%) | called by muse, mutect2, varscan2
- MOB3B | c.*3092T>C | 3'UTR (SNP) | VAF 48/75 reads (64%) | called by muse, varscan2
- MYO1E | c.-2C>T | 5'UTR (SNP) | VAF 32/62 reads (52%) | catalogued as rs573448797, COSV55686570; called by muse, varscan2
- MYO1E | c.-90A>C | 5'UTR (SNP) | VAF 70/141 reads (50%) | called by muse, mutect2
- MYO1E | c.-92C>T | 5'UTR (SNP) | VAF 70/142 reads (49%) | called by muse, mutect2
- MYO1E | c.-301G>T | 5'UTR (SNP) | VAF 99/225 reads (44%) | called by muse, mutect2, varscan2
- NAGK | c.580-73G>A | Intron (SNP) | VAF 94/193 reads (49%) | catalogued as rs561688594; called by muse, mutect2, varscan2
- NAPEPLD | c.*1851dup | 3'UTR (INS) | VAF 40/91 reads (44%) | called by mutect2, varscan2
- NCAM2 | c.*2264G>T | 3'UTR (SNP) | VAF 15/24 reads (63%) | called by muse, mutect2, varscan2
- NDUFS1 | c.*2144G>A | 3'UTR (SNP) | VAF 25/75 reads (33%) | called by muse, mutect2, varscan2
- NECTIN3-AS1 | n.530C>A | RNA (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2, varscan2
- NEK10 | c.3010+105C>T | Intron (SNP) | VAF 53/97 reads (55%) | called by muse, mutect2, varscan2
- NFYA | c.*984G>A | 3'UTR (SNP) | VAF 64/124 reads (52%) | called by muse, mutect2, varscan2
- NIPSNAP3A | c.*737C>A | 3'UTR (SNP) | VAF 46/106 reads (43%) | called by muse, mutect2, varscan2
- NKAIN3 | c.*53G>A | 3'UTR (SNP) | VAF 121/257 reads (47%) | called by muse, mutect2, varscan2
- NR0B1 | c.*240A>C | 3'UTR (SNP) | VAF 35/66 reads (53%) | called by muse, mutect2, varscan2
- NR2F2 | c.*1058G>T | 3'UTR (SNP) | VAF 18/38 reads (47%) | catalogued as rs1178105663; called by mutect2, varscan2
- NRXN1 | c.*111G>A | 3'UTR (SNP) | VAF 16/41 reads (39%) | catalogued as rs1558505772; called by muse, mutect2, varscan2
- NUFIP2 | c.*91G>T | 3'UTR (SNP) | VAF 52/127 reads (41%) | called by muse, mutect2, varscan2
- NUP62CL | c.*285T>C | 3'UTR (SNP) | VAF 20/49 reads (41%) | called by muse, mutect2, varscan2
- NUS1 | c.*3575C>T | 3'UTR (SNP) | VAF 18/36 reads (50%) | called by muse, mutect2, varscan2
- OR12D2 | c.*129dup | 3'UTR (INS) | VAF 32/60 reads (53%) | catalogued as rs535949013; called by mutect2, varscan2
- OR2T2 | chr1:248441302 C>A | 5'Flank (SNP) | VAF 87/169 reads (51%) | called by muse, mutect2, varscan2
- OSBPL5 | c.*204G>A | 3'UTR (SNP) | VAF 22/40 reads (55%) | called by muse, mutect2, varscan2
- P2RX4 | c.*253G>A | 3'UTR (SNP) | VAF 36/60 reads (60%) | called by muse, mutect2, varscan2
- PAPOLA | c.2005-9T>A | Intron (SNP) | VAF 22/62 reads (35%) | catalogued as rs201275170, COSV53478542, COSV53478897; called by muse, varscan2
- PCDH11X | c.-801T>G | 5'UTR (SNP) | VAF 81/185 reads (44%) | called by muse, mutect2, varscan2
- PCDH19 | c.-366G>A | 5'UTR (SNP) | VAF 47/93 reads (51%) | called by muse, mutect2, varscan2
- PDE3B | c.-129C>T | 5'UTR (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- PDE7B | c.*3202A>G | 3'UTR (SNP) | VAF 66/117 reads (56%) | called by muse, mutect2, varscan2
- PDIA3 | c.*494A>G | 3'UTR (SNP) | VAF 27/54 reads (50%) | called by muse, mutect2, varscan2
- PEF1 | c.*511C>T | 3'UTR (SNP) | VAF 53/114 reads (46%) | catalogued as rs957261797; called by muse, mutect2, varscan2
- PFAS | c.3706+26G>A | Intron (SNP) | VAF 100/183 reads (55%) | called by muse, mutect2, varscan2
- PGK1 | c.*949T>G | 3'UTR (SNP) | VAF 53/86 reads (62%) | called by muse, mutect2, varscan2
- PIP4K2B | c.*3163C>T | 3'UTR (SNP) | VAF 62/130 reads (48%) | catalogued as rs1376412453; called by muse, mutect2, varscan2
- PLXDC2 | c.-396G>T | 5'UTR (SNP) | VAF 92/178 reads (52%) | called by muse, mutect2, varscan2
- PPIF | c.*922T>C | 3'UTR (SNP) | VAF 82/184 reads (45%) | called by muse, mutect2, varscan2
- PREX2 | c.*3508G>T | 3'UTR (SNP) | VAF 34/66 reads (52%) | called by muse, mutect2, varscan2
- PREX2 | c.*3877T>G | 3'UTR (SNP) | VAF 37/83 reads (45%) | called by muse, mutect2, varscan2
- PRKAR2B | c.*813A>T | 3'UTR (SNP) | VAF 15/35 reads (43%) | catalogued as rs968670860; called by muse, mutect2, varscan2
- PRPF40A | c.*428dup | 3'UTR (INS) | VAF 42/105 reads (40%) | called by mutect2, pindel, varscan2
- PTPRJ | c.1615+1657del | Intron (DEL) | VAF 8/18 reads (44%) | catalogued as rs982073000; called by mutect2, varscan2
- PUS10 | c.127-1208G>A | Intron (SNP) | VAF 35/71 reads (49%) | called by muse, mutect2, varscan2
- PXYLP1 | c.*948C>T | 3'UTR (SNP) | VAF 33/96 reads (34%) | called by muse, mutect2, varscan2
- RAB39B | c.*2352T>A | 3'UTR (SNP) | VAF 26/50 reads (52%) | called by muse, mutect2, varscan2
- RABGEF1 | chr7:66811338 G>A | 3'Flank (SNP) | VAF 40/76 reads (53%) | catalogued as rs1448950553; called by muse, mutect2, varscan2
- RBM3 | chrX:48574501 G>A | 5'Flank (SNP) | VAF 49/86 reads (57%) | catalogued as rs984394838; called by muse, mutect2, varscan2
- RECQL5 | c.1718+24G>A | Intron (SNP) | VAF 29/55 reads (53%) | called by muse, mutect2, varscan2
- RN7SL860P | chr19:22603284 C>G | 3'Flank (SNP) | VAF 46/93 reads (49%) | called by muse, mutect2, varscan2
- RNF212 | c.*1352del | 3'UTR (DEL) | VAF 54/103 reads (52%) | catalogued as rs567247929; called by mutect2, varscan2
- RNF31 | c.2997-72G>T | Intron (SNP) | VAF 29/73 reads (40%) | called by muse, mutect2, varscan2
- RPL37 | c.*6818C>T | 3'UTR (SNP) | VAF 83/178 reads (47%) | called by muse, mutect2, varscan2
- RTF1 | c.*1673G>A | 3'UTR (SNP) | VAF 33/70 reads (47%) | called by muse, mutect2, varscan2
- SCUBE3 | c.*3187G>A | 3'UTR (SNP) | VAF 28/51 reads (55%) | called by muse, mutect2, varscan2
- SDAD1 | c.*623T>C | 3'UTR (SNP) | VAF 18/34 reads (53%) | called by muse, varscan2
- SEL1L3 | chr4:25863524 G>T | 5'Flank (SNP) | VAF 86/188 reads (46%) | called by muse, varscan2
- SEL1L3 | chr4:25863560 G>A | 5'Flank (SNP) | VAF 92/178 reads (52%) | catalogued as COSV53538382; called by muse, varscan2
- SELENON | chr1:25818265 C>T | 3'Flank (SNP) | VAF 18/28 reads (64%) | called by muse, mutect2, varscan2
- SEMA3E | c.*2644G>A | 3'UTR (SNP) | VAF 37/73 reads (51%) | called by muse, mutect2, varscan2
- SEMA6D | c.*1516A>C | 3'UTR (SNP) | VAF 45/96 reads (47%) | called by muse, mutect2, varscan2
- SEPTIN6 | chrX:119617397 T>A | 3'Flank (SNP) | VAF 32/88 reads (36%) | called by muse, mutect2, varscan2
- SF1 | c.31+201C>G | Intron (SNP) | VAF 5/9 reads (56%) | called by muse, mutect2, varscan2
- SFXN1 | c.*1770T>C | 3'UTR (SNP) | VAF 63/105 reads (60%) | called by muse, mutect2, varscan2
- SH3KBP1 | c.726+12913G>T | Intron (SNP) | VAF 110/300 reads (37%) | called by muse, mutect2, varscan2
- SHROOM4 | c.*997+50C>G | Intron (SNP) | VAF 27/88 reads (31%) | called by muse, mutect2, varscan2
- SLC39A8 | c.*504G>A | 3'UTR (SNP) | VAF 14/31 reads (45%) | called by muse, mutect2, varscan2
- SLCO5A1 | c.-193G>A | 5'UTR (SNP) | VAF 75/166 reads (45%) | called by muse, mutect2, varscan2
- SLIRP | chr14:77720528 C>T | 3'Flank (SNP) | VAF 71/157 reads (45%) | catalogued as rs1483661295; called by muse, mutect2, varscan2
- SLITRK1 | c.-639C>T | 5'UTR (SNP) | VAF 79/180 reads (44%) | called by muse, mutect2, varscan2
- SOX11 | c.*2304A>G | 3'UTR (SNP) | VAF 10/31 reads (32%) | called by muse, mutect2, varscan2
- SPAG16 | c.536+292C>T | Intron (SNP) | VAF 27/63 reads (43%) | called by muse, mutect2
- SPATA6 | c.*2151A>G | 3'UTR (SNP) | VAF 38/39 reads (97%) | called by muse, mutect2, varscan2
- SPRY3 | c.*5817T>G | 3'UTR (SNP) | VAF 101/189 reads (53%) | called by muse, mutect2, varscan2
- SQLE | c.291+328C>A | Intron (SNP) | VAF 262/402 reads (65%) | catalogued as rs1211580087; called by muse, varscan2
- SSPOP | n.4884G>A | RNA (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
- STAU2 | chr8:73747467 G>A | 5'Flank (SNP) | VAF 78/150 reads (52%) | called by muse, mutect2, varscan2
- STEAP2 | c.*4619C>A | 3'UTR (SNP) | VAF 36/88 reads (41%) | called by muse, mutect2, varscan2
- STK17B | c.*1297A>G | 3'UTR (SNP) | VAF 47/97 reads (48%) | catalogued as rs530649451; called by muse, mutect2, varscan2
- TBC1D5 | c.*787A>C | 3'UTR (SNP) | VAF 30/70 reads (43%) | called by muse, mutect2, varscan2
- TCP11X3P | n.1128T>C | RNA (SNP) | VAF 87/174 reads (50%) | called by muse, mutect2, varscan2
- TECRL | chr4:64276710 C>A | 3'Flank (SNP) | VAF 17/47 reads (36%) | catalogued as rs916773145; called by muse, mutect2, varscan2
- TEKT1 | c.*889A>C | 3'UTR (SNP) | VAF 51/110 reads (46%) | called by muse, mutect2, varscan2
- TENM2 | chr5:168263703 G>C | 3'Flank (SNP) | VAF 33/61 reads (54%) | called by muse, mutect2, varscan2
- TENT5A | c.*1419del | 3'UTR (DEL) | VAF 26/50 reads (52%) | catalogued as rs961290506; called by mutect2, varscan2
- TFPI2 | c.*934G>A | 3'UTR (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2, varscan2
- TIRAP | c.*901C>T | 3'UTR (SNP) | VAF 283/613 reads (46%) | called by muse, mutect2, varscan2
- TMC2 | c.83-10G>A | Intron (SNP) | VAF 36/66 reads (55%) | catalogued as rs1329804673; called by muse, mutect2, varscan2
- TMCC1 | c.*1124G>A | 3'UTR (SNP) | VAF 76/153 reads (50%) | called by muse, mutect2, varscan2
- TMEM116 | c.-301G>C | 5'UTR (SNP) | VAF 58/140 reads (41%) | called by muse, mutect2, varscan2
- TMEM164 | c.*2665G>A | 3'UTR (SNP) | VAF 165/340 reads (49%) | catalogued as rs1350596148; called by muse, mutect2, varscan2
- TMEM182 | chr2:102762018 G>A | 5'Flank (SNP) | VAF 16/39 reads (41%) | catalogued as rs959555859; called by muse, mutect2, varscan2
- TMEM183A | c.*1446_*1447del | 3'UTR (DEL) | VAF 8/35 reads (23%) | catalogued as rs1241695825; called by pindel, varscan2
- TMEM30A | c.*1497T>A | 3'UTR (SNP) | VAF 33/56 reads (59%) | catalogued as rs559748543, COSV57874943; called by muse, mutect2, varscan2
- TMEM80 | c.460+347A>G | Intron (SNP) | VAF 116/247 reads (47%) | catalogued as rs1380396734; called by muse, mutect2, varscan2
- TMSB4X | chrX:12975473 A>G | 5'Flank (SNP) | VAF 99/217 reads (46%) | called by muse, mutect2, varscan2
- TMSB4X | c.*244G>C | 3'UTR (SNP) | VAF 38/85 reads (45%) | called by muse, mutect2, varscan2
- TMX4 | c.*1926C>T | 3'UTR (SNP) | VAF 50/97 reads (52%) | called by muse, mutect2, varscan2
- TNRC6A | c.*1190T>A | 3'UTR (SNP) | VAF 40/95 reads (42%) | called by muse, mutect2, varscan2
- TP63 | c.*1594T>G | 3'UTR (SNP) | VAF 42/81 reads (52%) | called by muse, mutect2, varscan2
- TUBGCP3 | c.1168+102G>A | Intron (SNP) | VAF 12/14 reads (86%) | catalogued as rs779748161; called by muse, varscan2
- TYRO3 | c.*192C>T | 3'UTR (SNP) | VAF 24/72 reads (33%) | catalogued as rs1232182418; called by muse, mutect2, varscan2
- UNC79 | chr14:93430853 T>C | 5'Flank (SNP) | VAF 17/31 reads (55%) | called by muse, mutect2, varscan2
- VGF | c.*210G>A | 3'UTR (SNP) | VAF 60/108 reads (56%) | catalogued as rs868168937; called by muse, mutect2, varscan2
- VWA5A | c.*97C>T | 3'UTR (SNP) | VAF 60/134 reads (45%) | called by muse, mutect2
- YES1 | c.*156dup | 3'UTR (INS) | VAF 48/96 reads (50%) | catalogued as rs1319799918; called by mutect2, varscan2
- ZDHHC14 | c.-829C>T | 5'UTR (SNP) | VAF 31/66 reads (47%) | called by muse, mutect2, varscan2
- ZFHX4 | c.*2243A>G | 3'UTR (SNP) | VAF 16/39 reads (41%) | catalogued as rs72659527, COSV50983696; called by mutect2, varscan2
- ZMYND8 | c.*319A>C | 3'UTR (SNP) | VAF 12/34 reads (35%) | called by mutect2, varscan2
- ZNF322 | c.*154G>T | 3'UTR (SNP) | VAF 5/19 reads (26%) | called by mutect2, varscan2
- ZNF420 | c.*1059dup | 3'UTR (INS) | VAF 124/220 reads (56%) | called by mutect2, varscan2
- ZNF606 | c.88+173G>A | Intron (SNP) | VAF 16/47 reads (34%) | catalogued as rs750722060; called by muse, mutect2, varscan2
- ZNF687 | c.*238T>G | 3'UTR (SNP) | VAF 158/159 reads (99%) | called by muse, mutect2, varscan2
- ZNF813 | c.*2284G>A | 3'UTR (SNP) | VAF 6/17 reads (35%) | catalogued as rs936268447; called by muse, mutect2
- ZNF880 | chr19:52390266 G>A | 3'Flank (SNP) | VAF 28/59 reads (47%) | catalogued as rs775422786; called by muse, mutect2, varscan2
